Somatic mutation profile of tumor specimen TCGA-2Z-A9JI-01A (aliquot TCGA-2Z-A9JI-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 38.9 years (14,196 days).
Specimen TCGA-2Z-A9JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e609430c-65c9-4fa4-80e7-4e8255f7e717.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JI-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JI-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad5b8a88-07c2-4e35-a1e4-6e5a50c96f51

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF4G1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100071836; called by muse, mutect2, varscan2
- ERVFRD-1 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.376); catalogued as COSV100977398; called by muse, mutect2, varscan2
- JAK1 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100691769; called by muse, mutect2
- KRT24 | c.1326C>G p.I442M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778819567, COSV99232034; called by muse, mutect2, varscan2
- MARCO | c.201T>A p.V67= | Splice Region (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100503504; called by muse, mutect2, varscan2
- PCGF2 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1186813888; called by muse, mutect2
- PRKDC | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | catalogued as COSV100040777; called by muse, mutect2, varscan2
- AP3M1 | c.636A>G p.L212= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100786712; called by muse, mutect2, varscan2
- ETV1 | c.1038T>C p.D346= | Silent (SNP) | VAF 29/206 reads (14%) | catalogued as COSV99623558; called by muse, mutect2, varscan2
